Somatic mutation profile of tumor specimen C3N-02599-03 (aliquot CPT0224840006) from CPTAC case C3N-02599, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.3 years (23,847 days).
Specimen C3N-02599-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29321f30-f541-44f2-b0e4-9e912629bc71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02599-31 (Blood Derived Normal), aliquot CPT0224860002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ff12776-6222-489b-89cb-a352901bdf77

The open-access MAF lists 79 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Nonsense Mutation 5, Intron 3, Splice Site 2, 3'Flank 2, RNA 2, 5'UTR 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 126/4034 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA10 | c.2851G>A p.G951S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs769137596; called by muse, mutect2, varscan2
- ANK3 | c.10679G>A p.R3560Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as rs756241696, COSV55061219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCN5 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs969536571; called by muse, mutect2, varscan2
- DCAF4 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 43/120 reads (36%) | catalogued as rs888106593; called by muse, mutect2, varscan2
- DNAJB11 | c.907G>C p.G303R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99408585; called by muse, mutect2
- EGFR | c.685A>T p.S229C | Missense Mutation (SNP) | VAF 924/3996 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51827895; called by muse, mutect2, varscan2
- HAPLN4 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.691); catalogued as COSV52270830; called by muse, mutect2, varscan2
- IGKV6D-21 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 95/280 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs756883108; called by muse, mutect2, varscan2
- IL31RA | c.2114C>A p.S705* | Nonsense Mutation (SNP) | VAF 44/146 reads (30%) | catalogued as COSV61692662; called by muse, mutect2, varscan2
- IZUMO1R | c.440G>A p.R147H (on ENST00000440961; = p.R154H on NM_001199206.3) | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368760432, COSV60623714; called by muse, mutect2, varscan2
- KCNQ5 | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 140/420 reads (33%) | catalogued as COSV59671908; called by muse, mutect2, varscan2
- KMO | c.1015+6_1015+9del p.X339_splice | Splice Site (DEL) | VAF 13/50 reads (26%) | catalogued as rs1331858716; called by pindel, varscan2
- PCDHGA5 | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.195); catalogued as rs188773052, COSV54007929, COSV54051186; called by muse, mutect2, varscan2
- PIK3R6 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs200325102; called by muse, mutect2
- PRB4 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as rs374434768, COSV99686470; called by muse, mutect2, varscan2
- SBF1 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.172); catalogued as rs372926692; called by muse, mutect2, varscan2
- SCN9A | c.5656C>T p.R1886W (on ENST00000303354; = p.R1875W on NM_002977.3) | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs560168893, COSV57599473; called by muse, mutect2, varscan2
- SIN3A | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV64585130; called by muse, varscan2
- TRBC2 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 104/406 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as rs782603398; called by muse, mutect2, varscan2
- TTLL10 | c.572C>T p.T191M (on ENST00000379289 / NM_001130045.2; = p.T118M on NM_153254.3) | Missense Mutation (SNP) | VAF 119/339 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs775102650, COSV101016904; called by muse, mutect2, varscan2
- ZNF462 | c.1937A>C p.D646A | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as COSV52950022; called by muse, mutect2, varscan2
- A4GNT | c.297C>G p.N99K | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- AL139011.2 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 84/317 reads (26%) | PolyPhen benign (0.021); called by mutect2, varscan2
- ALG13 | c.4A>C p.K2Q | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDH6 | c.1714G>C p.D572H | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLCA4 | c.2224T>G p.S742A | Missense Mutation (SNP) | VAF 115/333 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- DCD | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 112/353 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- DNAAF3 | c.656A>T p.D219V (on ENST00000524407 / NM_001256715.2; = p.D266V on NM_178837.4) | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOCK5 | c.1526G>A p.W509* | Nonsense Mutation (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- DPM1 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- FCGR2A | c.19A>G p.M7V | Missense Mutation (SNP) | VAF 8/230 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- GABPB2 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- GNRHR | c.408C>A p.S136R | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GORAB | c.984G>C p.K328N | Missense Mutation (SNP) | VAF 16/516 reads (3%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); called by muse, mutect2
- ICA1L | c.121C>A p.H41N | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- KATNA1 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- LANCL2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 610/767 reads (80%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MUC16 | c.34895C>A p.T11632N | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- NLRP14 | c.2585T>C p.L862P | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- PBDC1 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- PDGFRA | c.802T>C p.S268P | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PGAM4 | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 90/258 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PRKDC | c.2053-1G>A p.X685_splice | Splice Site (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
- RFX1 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- TEAD4 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TJP1 | c.2426C>A p.T809K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.468); called by muse, varscan2
- TMEFF2 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPTE | c.1320G>T p.K440N (on ENST00000618007 / NM_199261.4; = p.K422N on NM_199259.4) | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- WDFY3 | c.4626A>T p.E1542D | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF658 | c.1429T>C p.Y477H | Missense Mutation (SNP) | VAF 76/386 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, varscan2
- ZNF99 | c.1845T>A p.H615Q | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ABCA1 | c.6423A>T p.I2141= | Silent (SNP) | VAF 78/218 reads (36%) | called by muse, mutect2, varscan2
- ABCC2 | c.396G>T p.L132= | Silent (SNP) | VAF 120/220 reads (55%) | called by muse, mutect2, varscan2
- AOC1 | c.2073C>A p.S691= | Silent (SNP) | VAF 54/294 reads (18%) | catalogued as rs372013575, COSV100710729; called by muse, mutect2, varscan2
- CDC42BPA | c.4206A>G p.L1402= (on ENST00000334218 / NM_001366019.2; = p.L1389= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs370253635; called by muse, mutect2, varscan2
- CDS1 | c.705G>C p.L235= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- CNOT4 | c.861C>T p.N287= (on ENST00000315544 / NM_001190848.1; = p.N284= on NM_013316.4) | Silent (SNP) | VAF 38/208 reads (18%) | catalogued as rs375226749; called by muse, mutect2, varscan2
- GRK4 | c.894C>T p.C298= (on ENST00000398052 / NM_182982.3; = p.C266= on NM_005307.3) | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs770625534; called by muse, mutect2, varscan2
- IGHD | c.885G>A p.E295= | Silent (SNP) | VAF 15/404 reads (4%) | called by muse, mutect2
- LY96 | c.132T>C p.I44= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
- MUC12 | c.1026C>T p.I342= (on ENST00000379442; = p.I199= on NM_001164462.1) | Silent (SNP) | VAF 129/465 reads (28%) | called by muse, mutect2, varscan2
- MUC16 | c.20298G>A p.S6766= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as rs267605796, COSV67495777; called by muse, mutect2, varscan2
- PCDHA1 | c.2157G>A p.T719= | Silent (SNP) | VAF 148/385 reads (38%) | called by muse, varscan2
- PCDHGB2 | c.1803C>T p.N601= | Silent (SNP) | VAF 105/347 reads (30%) | catalogued as rs778338184, COSV99531734; called by muse, mutect2, varscan2
- PSG5 | c.846A>G p.S282= | Silent (SNP) | VAF 22/276 reads (8%) | catalogued as rs760787213; called by muse, mutect2
- RASGEF1A | c.516C>A p.S172= | Silent (SNP) | VAF 28/224 reads (13%) | called by muse, mutect2, varscan2
- S1PR5 | c.250C>T p.L84= | Silent (SNP) | VAF 116/438 reads (26%) | called by muse, mutect2, varscan2
- SPATS2L | c.1128G>A p.A376= | Silent (SNP) | VAF 109/346 reads (32%) | catalogued as rs752637429; called by muse, mutect2, varscan2
- AFDN | chr6:167976372 G>A | 3'Flank (SNP) | VAF 4/11 reads (36%) | catalogued as rs111332561; called by muse, varscan2
- ATP6V0B | c.*21C>T | 3'UTR (SNP) | VAF 28/181 reads (15%) | catalogued as rs755472183; called by muse, mutect2, varscan2
- C16orf97 | n.375G>A | RNA (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- CCDC66 | c.936+1092G>A | Intron (SNP) | VAF 60/151 reads (40%) | called by muse, mutect2, varscan2
- FAM83G | c.2082+647G>A | Intron (SNP) | VAF 82/334 reads (25%) | called by muse, mutect2
- OR5E1P | n.742G>A | RNA (SNP) | VAF 22/260 reads (8%) | catalogued as rs1043765023; called by muse, mutect2
- RNA5-8SP2 | chr16:34159700 G>A | 5'Flank (SNP) | VAF 85/256 reads (33%) | called by mutect2, varscan2
- UQCRB | c.19+1054C>G | Intron (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- VRK3 | chr19:49971670 C>T | 3'Flank (SNP) | VAF 34/132 reads (26%) | called by muse, mutect2, varscan2
- VWA1 | c.-12C>T | 5'UTR (SNP) | VAF 48/101 reads (48%) | catalogued as rs1192185159, COSV58600634; called by muse, mutect2, varscan2
